Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A05P, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A05P-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY
- 2: Sentinel lymph node, right external iliac; excision
- 3: Lymph nodes, left obturator; excision
- 4: Lymph nodes, left external iliac; excision
- 5: Lymph nodes, left common iliac; excision

DIAGNOSIS:

1. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

Tumor Type:

Adenocarcinoma, endometrioid type

Architectural Grade (For Endometrioid Types only):

I (<6% solid growth)

Nuclear Grade (For Endometrioid Types only):

Grade 1

FIGO Grade (For Endometrioid Types only):

Grade 1

Myometrial Invasion:

Not identified

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Not identified

Endometrium:

Exhibits complex hyperplasia with atypia

Myometrium:

Unremarkable

Adnexa:

Unremarkable

Comment:

Benign endocervical polyp is noted

ICD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1 /w 5/2/11

2. SENTINEL LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1)
- MULTIPLE LEVELS AND CYTOKERATIN IMMUNOSTAINED SLIDES WERE EXAMINED.

** Continued on next page **

	/w 5/2/11	

[page 2 of 2]
3. LYMPH NODES, LEFT OBTURATOR; EXCISION:
-ONE BENIGN LYMPH NODE (0/1)
4. LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
-BENIGN FIBROADIPOSE TISSUE (TISSUE ENTIRELY SUBMITTED)
5. LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
-TWO BENIGN LYMPH NODES (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 266cf6cb-5bf5-4122-8e6e-384b1d576f3c (TCGA-AP-A05P.5BA23C70-805A-4356-B739-AFBAFD29D7FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).